MMRF case MMRF_2129 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0ff341b1-82f1-499d-8e8c-3d8561e65697

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.6 years (22,865 days); ISS stage: I; Days to last known disease status: 904 days (2.5 years); Days to last follow up: 904 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 49 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 151 days; Days to treatment end: 151 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 175 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 176 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 96.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.281 mg/dL; Immunoglobulin G 3.21 g/L; Immunoglobulin A 41.7 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.6 mmol/L; Albumin 39 g/L; Total Protein 10.1 g/dL; Glucose 5.23 mmol/L.
- Day 70 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.215 mg/dL; Immunoglobulin G 3.19 g/L; Immunoglobulin A 22.1 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 476 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 4.13 mmol/L.
- Day 187 (ECOG 1): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.741 mg/dL; Immunoglobulin G 2.95 g/L; Immunoglobulin A 8.03 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1 µg/mL; Lactate Dehydrogenase 6.17 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 0.4 ×10⁹/L; Absolute Neutrophil 0.3 ×10⁹/L; Platelets 27 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 5.3 g/dL; Glucose 5.78 mmol/L.
- Day 302 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 2.49 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 353 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.34 mmol/L.
- Day 400 (ECOG 1): M Protein 0.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 2.4 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 8.18 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 5.78 mmol/L.
- Day 498 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.88 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 3.19 g/L; Immunoglobulin M 0.83 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 385 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 4.95 mmol/L.
- Day 595 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 2.41 g/L; Immunoglobulin M 0.66 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 341 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.5 mmol/L.
- Day 714 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 2.95 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 813 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.96 g/L; Immunoglobulin M 0.76 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 347 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 5.34 mmol/L.
- Day 904 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 2.97 g/L; Immunoglobulin M 0.73 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 305 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day -6: Weight: 66 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2129_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2129_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
